Somatic mutation profile of tumor specimen TCGA-G9-6332-01A (aliquot TCGA-G9-6332-01A-11D-1786-08) from TCGA case TCGA-G9-6332, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.2 years (20,166 days).
Specimen TCGA-G9-6332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6051ae0-b1e4-43ae-948f-2f79d81b5b8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6332-10A (Blood Derived Normal), aliquot TCGA-G9-6332-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4ceee4c-118f-4186-8895-d9d5b446a829

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Frame Shift Ins 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs368867511; called by muse, mutect2, varscan2
- ANKRD20A1 | c.770_772del p.K257del | In Frame Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs1441578737; called by pindel, varscan2
- ARHGEF15 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs771433483, COSV62724589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATF6B | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV64322856; called by muse, varscan2
- CABP5 | c.497-1G>A p.X166_splice | Splice Site (SNP) | VAF 35/105 reads (33%) | catalogued as COSV53154104; called by muse, mutect2, varscan2
- CCDC34 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV58727078; called by muse, mutect2, varscan2
- CDH5 | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs746212904, COSV58516627, COSV58519189; called by muse, mutect2, varscan2
- CSMD3 | c.4687G>A p.E1563K (on ENST00000297405 / NM_001363185.1; = p.E1459K on NM_052900.3) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV52317655; called by muse, mutect2, varscan2
- HCN4 | c.2978C>A p.T993K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.001); catalogued as COSV56087347; called by muse, mutect2, varscan2
- HPS1 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs780093504, COSV57268129; called by muse, mutect2, varscan2
- KCNJ11 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV60595512; called by muse, mutect2
- LIMK1 | c.19T>G p.C7G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as COSV60284582; called by muse, mutect2, varscan2
- MPEG1 | c.2003T>G p.L668R | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57095011; called by muse, mutect2, varscan2
- OR4C3 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138317832; called by muse, varscan2
- OR4D9 | c.204T>G p.I68M | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV61435570; called by muse, mutect2, varscan2
- PRKCSH | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as CM063069, COSV52954101; called by muse, mutect2, varscan2
- RASAL1 | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs753259896, COSV55659732; called by muse, mutect2, varscan2
- RIPK1 | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV52531766; called by muse, mutect2, varscan2
- TTN | c.88678T>C p.F29560L (on ENST00000591111; = p.F22136L on NM_003319.4) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | PolyPhen benign (0.041); catalogued as rs1553528695, COSV60346006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VARS1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199533729, COSV65154658; called by muse, mutect2, varscan2
- PMEL | c.1909_1919del p.W637Tfs*11 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by mutect2, pindel, varscan2
- UBR3 | c.5306_5307insTCAG p.T1770Qfs*6 | Frame Shift Ins (INS) | VAF 5/88 reads (6%) | called by muse*, mutect2
- AGBL1 | c.2331G>A p.T777= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as rs1222187249, COSV66853203, COSV66854154; called by muse, mutect2, varscan2
- DENND2D | c.753C>T p.A251= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs751654447, COSV62960156; called by muse, mutect2, varscan2
- GRK2 | c.1917G>A p.E639= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV57754699; called by muse, mutect2, varscan2
- KCNJ11 | c.363C>T p.F121= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1424040124, COSV60595523; called by muse, mutect2
- SEPHS1 | c.522A>G p.G174= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV59260914; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502465 A>T | 5'Flank (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- SNAP25 | c.164-247C>G | Intron (SNP) | VAF 12/98 reads (12%) | catalogued as COSV54775755; called by muse, mutect2, varscan2
